Surgical pathology report (de-identified scan), TCGA case TCGA-HC-8213, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-HC-8213-01A (Primary Tumor).

Sex: [REDACTED]
D.O.B.: [REDACTED]
MRN #: [REDACTED]
Ref Phy: [REDACTED]

SPECIMEN INFORMATION

SURGICAL PATHOLOGY REPORT

DIAGNOSIS

DIAGNOSIS:

Prostate:

Tumor Characteristics:

1. Histologic type: Adenocarcinoma.
2. Prostate size: 4.5 x 4.5 x 3.1 cm, 48 grams.
3. Tumor quantitation: Neoplasm accounts for less than 2% of the prostatic tissue examined.
4. Gleason grade:
- a. Primary pattern: 3/5.
- b. Secondary pattern: 3/5.
- c. Total Gleason score: 6/10.
5. Extraprostatic extension: No.
6. Seminal vesicle involvement: No.
7. Lymphovascular space invasion: No intraluminal neoplasm is identified.
8. High grade PIN: Absent.

Surgical Margin Status:

All surgical margins are uninvolved by neoplasm.

Lymph Node Status:

Not applicable.

Other:

pTNM stage: pT2c NX MX.

Electronic Signature: [REDACTED]

CLINICAL INFORMATION

CLINICAL HISTORY:

Preoperative Diagnosis: Malignant neoplasm prostate

Postoperative Diagnosis:

Symptoms/Radiologic Findings:

SPECIMENS:

Prostate

SPECIMEN DATA

GROSS DESCRIPTION:

The specimen is received labeled prostate. The specimen consists of an intact prostate gland with attached bilateral seminal vesicles and vas deferens. The prostate measures 4.5 x 4.5 x 3.1 cm and weighs 48 grams. The surface of the prostate is gray to brown tan with adhesions. The bilateral seminal vesicles measure on average 4.5 cm in length and 0.7 cm in diameter with a vas deferens measuring 4.5 cm in length and 0.5 cm in diameter and are also grossly unremarkable. The right half of the prostate has been inked blue and the left half has been inked black. The specimen is serially sectioned from apex to base and reveals the cut surface is yellow gray tan fibrous and nodular. A well defined mass is not identified grossly. Received with the specimen are two cassettes, one green, one yellow labeled [REDACTED] with the yellow one additionally labeled -16 and the green one additionally labeled -17. Representative sections are submitted in cassettes as follows: Right seminal vesicle and vas block 1; left seminal vesicle and vas block 2; perpendicular sections taken from the margins from the apex block 3; base block 4; prostate submitted from apex to base as follows: Level I, left anterior block 5; left posterior block 6; right posterior block 7; right anterior block 8; level II, left anterior block 9; left posterior block 10; right posterior block 11; right anterior block 12; level III, left anterior block 13; left posterior block 14; right posterior block 15; right anterior block 16.

Source: NCI Genomic Data Commons file 395c3f47-a249-4cde-924f-50f34f8dd860 (TCGA-HC-8213.E6CE4E34-DE42-455C-AD93-CCE42FCFE049.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).